Somatic mutation profile of tumor specimen TCGA-A7-A0CJ-01A (aliquot TCGA-A7-A0CJ-01A-21W-A019-09) from TCGA case TCGA-A7-A0CJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.5 years (21,014 days).
Specimen TCGA-A7-A0CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c0dbc07-6215-4838-a045-0b50d204868b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A0CJ-10A (Blood Derived Normal), aliquot TCGA-A7-A0CJ-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/919fc80a-c686-481c-bcfc-2a38a0b76ae1

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 1, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 78/162 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 61/81 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS2 | c.2555A>G p.D852G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.35); catalogued as COSV99284035; called by muse, mutect2
- AGPAT1 | c.510+1G>A p.X170_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | catalogued as COSV61247725; called by muse, mutect2, varscan2
- AKAP3 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV57418847; called by muse, mutect2
- ARHGAP36 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 426/566 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52272271; called by muse, mutect2, varscan2
- ATP8B1 | c.2584G>T p.A862S | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV52178009, COSV52180527; called by muse, mutect2, varscan2
- BCAP31 | c.650A>T p.E217V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100799011; called by muse, mutect2
- C9orf131 | c.1841C>A p.A614D | Missense Mutation (SNP) | VAF 294/398 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV56610303; called by muse, mutect2
- CADM2 | c.446C>G p.S149C (on ENST00000407528 / NM_001167674.2; = p.S151C on NM_153184.4) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV101054517, COSV67405972; called by muse, mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 56/510 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CCDC30 | c.916C>T p.R306* (on ENST00000340612; = p.R263* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 68/231 reads (29%) | catalogued as rs780702656, COSV59604704; called by muse, mutect2, varscan2
- CHD6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 75/593 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.462); catalogued as COSV58562639; called by muse, mutect2, varscan2
- DAB2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs376782436; called by muse, mutect2, varscan2
- DIP2C | c.4358G>A p.R1453Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs1425181510, COSV55180001; called by muse, mutect2, varscan2
- DSG4 | c.1274T>A p.V425D | Missense Mutation (SNP) | VAF 85/345 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57397960; called by muse, mutect2, varscan2
- FCAR | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs375603668; called by muse, mutect2, varscan2
- GPR34 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59375893; called by muse, mutect2, varscan2
- HOXA2 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.096); catalogued as rs762322767, COSV56067301; called by muse, mutect2, varscan2
- LRP12 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs147788045; called by muse, mutect2, varscan2
- MOB1B | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 19/307 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100511680; called by muse, mutect2
- MUC16 | c.16838C>T p.T5613I | Missense Mutation (SNP) | VAF 122/570 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs760085929, COSV67495632; called by muse, mutect2, varscan2
- OR10A4 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 218/502 reads (43%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.965); catalogued as rs1354907152, COSV65842554; called by muse, mutect2, varscan2
- PADI1 | c.1343T>C p.V448A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372098470; called by muse, mutect2, varscan2
- POLQ | c.7772A>C p.*2591Sext*4 | Nonstop Mutation (SNP) | VAF 70/149 reads (47%) | catalogued as COSV51761908; called by muse, mutect2, varscan2
- PRKD2 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750665196, COSV52189907; called by muse, mutect2, varscan2
- RIOX1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 58/82 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1209953502, COSV100408124; called by muse, mutect2
- SGO1 | c.1469C>T p.A490V (on ENST00000263753 / NM_001012410.5; = p.A221V on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV55425356; called by muse, mutect2, varscan2
- SGSM3 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763175054, COSV50655576; called by muse, mutect2, varscan2
- SIMC1 | c.1348C>G p.L450V (on ENST00000443967 / NM_001308196.1; = p.L469V on NM_001308195.2) | Missense Mutation (SNP) | VAF 68/317 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.999); catalogued as COSV57907302; called by muse, varscan2
- SLC38A4 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV99873196; called by muse, mutect2
- TMCC2 | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58006621; called by muse, mutect2, varscan2
- TMEM219 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.814); catalogued as COSV54244797; called by muse, mutect2, varscan2
- TMEM219 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.479); catalogued as COSV54244809; called by muse, mutect2, varscan2
- TRO | c.2304del p.F769Sfs*13 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as COSV51508184; called by mutect2, pindel, varscan2
- TTN | c.15571G>A p.E5191K (on ENST00000591111; = p.E4264K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | PolyPhen possibly damaging (0.814); catalogued as rs868059813, COSV60191281; called by muse, mutect2, varscan2
- ZBTB39 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV100267872, COSV55630968; called by muse, mutect2, varscan2
- ZFP64 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV53798154, COSV53804061; called by muse, mutect2, varscan2
- ZNF425 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.748); catalogued as COSV100955623; called by muse, mutect2, varscan2
- ZSWIM2 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54579801; called by muse, mutect2, varscan2
- NAGA | c.751_756del p.P251_D252del | In Frame Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- NBPF26 | c.3773T>C p.I1258T (on ENST00000620612; = p.I996T on NM_001351372.1) | Missense Mutation (SNP) | VAF 3/374 reads (1%) | SIFT tolerated (0.4); PolyPhen benign (0.158); called by muse, mutect2
- TRMT61B | c.1039dup p.Y347Lfs*5 | Frame Shift Ins (INS) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- ACOT2 | c.1254A>G p.P418= | Silent (SNP) | VAF 28/245 reads (11%) | catalogued as COSV53151628; called by muse, mutect2, varscan2
- CDK18 | c.513G>T p.L171= (on ENST00000506784 / NM_212503.3; = p.L141= on NM_002596.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV63728986; called by muse, mutect2, varscan2
- CYP26B1 | c.510C>T p.R170= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs145145054; called by muse, mutect2, varscan2
- FAM3C | c.237C>T p.N79= | Silent (SNP) | VAF 50/205 reads (24%) | catalogued as rs1396974289, COSV63436640; called by muse, mutect2, varscan2
- LSM14A | c.483G>A p.A161= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as rs773011768, COSV101471745, COSV70885734; called by muse, mutect2, varscan2
- MFN2 | c.537G>A p.V179= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV99337124; called by muse, mutect2, varscan2
- MKI67 | c.1101T>C p.Y367= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs770183077, COSV100897030; called by muse, mutect2
- MYO15A | c.5550C>T p.A1850= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV52766762; called by muse, mutect2, varscan2
- NT5C1B | c.1605G>C p.L535= (on ENST00000359846 / NM_001199086.2; = p.L475= on NM_033253.4) | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs984281105, COSV100410200, COSV58399218; called by muse, mutect2, varscan2
- PRDM2 | c.1887G>A p.L629= | Silent (SNP) | VAF 137/251 reads (55%) | catalogued as rs746581471, COSV52456116; called by muse, mutect2, varscan2
- RCL1 | c.627G>T p.V209= | Silent (SNP) | VAF 199/292 reads (68%) | catalogued as COSV67754474; called by muse, mutect2, varscan2
- TUBE1 | c.744A>G p.K248= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV64088165; called by muse, mutect2, varscan2
